Somatic mutation profile of tumor specimen TARGET-20-PASRTP-09A (aliquot TARGET-20-PASRTP-09A-01D) from TARGET case TARGET-20-PASRTP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,389 days).
Specimen TARGET-20-PASRTP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f53622-5a10-4311-9959-6f3c934f9a73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASRTP-14A (Bone Marrow Normal), aliquot TARGET-20-PASRTP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89aca62e-85f7-4dc0-bdbb-7885300b24c6

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.213T>G p.F71L | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1555267558, COSV61005635, COSV61011607; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DOCK9 | c.962G>A p.S321N (on ENST00000376460 / NM_001366676.2; = p.S322N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 276/595 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1298634667, COSV59639285; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 143/332 reads (43%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- PCDHB2 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.8); catalogued as rs782784687, COSV52030220, COSV52033669; called by muse, mutect2, varscan2
- OR2A7 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, varscan2
- JARID2 | c.3159T>C p.A1053= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV59195104; called by muse, mutect2, varscan2
- MYADML2 | c.303G>C p.T101= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
